TARGET case TARGET-20-PAUPDK — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fb60f95a-e263-4b58-be90-e23446038217

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 1 day.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 4.1 years (1,507 days); Year of diagnosis: 2011; Days to last follow up: 1 day; Sites of involvement: Central nervous system.
   Treatment given: Protocol identifier: AAML1031.
   Treatment given: Reason treatment ended: Death; Course number: 1; Timepoint category: End of Treatment Course.
   Treatment given: Reason treatment ended: Death; Course number: 2; Timepoint category: End of Treatment Course.
   Recorded as not given: Stem Cell Transplantation, NOS, first complete response.

Follow-up (1 entry)
- Days to follow up: 1 day; Days to first event: 1 day; First event: Death without Remission; Year of follow up: 2011.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- CEBPA mutation, nos: Negative.
- FLT3 internal tandem duplication: Negative.
- KMT2A translocation: Negative.
- Monosomy 5: Negative.
- Monosomy 7: Negative.
- NPM1 mutation, nos: Negative.
- Test: Negative.
- Test: Negative; Chromosomal translocation: t(10;11)(p11.2;q23).
- Test: Negative; Chromosomal translocation: t(11;19)(q23;p13.1).
- Test: Negative; Chromosomal translocation: t(3;5)(q25;q34).
- Test: Negative; Chromosomal translocation: t(6;11)(q27;q23).
- Test: Negative; Chromosomal translocation: t(6;9).
- Test: Negative; Chromosomal translocation: t(8;21).
- Test: Negative; Chromosomal translocation: t(9;11)(p22;q23).
- Test: Negative; Chromosome arm: q.
- Trisomy 21: Negative.
- Trisomy 8: Negative.
- Day 0: Leukocytes 445 ×10³/µL; Blast Count 93%.

Other clinical attributes
- Day 0: Comorbidities: Chloroma; Risk factors: Chloroma.

Biospecimens (1 sample)
- Sample TARGET-20-PAUPDK-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_AML1031_20230720.xlsx (sheet Clinical Data):
- Event Free Survival Time in Days: 1
- Overall Survival Time in Days: 1
- WBC at Diagnosis: 444.7
- Peripheral blasts (%): 93
- CNS disease: Yes
- Chloroma: Yes
- t(6;9): No
- t(8;21): No
- t(3;5)(q25;q34): No
- t(6;11)(q27;q23): No
- t(9;11)(p22;q23): No
- t(10;11)(p11.2;q23): No
- t(11:19)(q23:p13.1): No
- inv(16): No
- del5q: No
- del7q: No
- del9q: No
- monosomy 5: No
- monosomy 7: No
- trisomy 8: No
- trisomy 21: No
- MLL: No
- Minus Y: No
- Minus X: No
- Cytogenetic Code Other: add(17)(q25)
- Cytogenetic Complexity: 3
- Primary Cytogenetic Code: Other
- ISCN: 46,XY,t(2;11)(q31;p15),add(12)(p13),add(17)(q25)[20]
- FLT3/ITD positive?: No
- NPM mutation: No
- CEBPA mutation: No
- Risk group: Standard Risk
- SCT in 1st CR: No
